Somatic mutation profile of tumor specimen TCGA-BR-4370-01A (aliquot TCGA-BR-4370-01A-01D-1158-08) from TCGA case TCGA-BR-4370, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; Tumor grade: G2; Age at diagnosis: 74.9 years (27,344 days).
Specimen TCGA-BR-4370-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 188b758a-25b3-4e78-a765-f53d72edc24d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4370-11A (Solid Tissue Normal), aliquot TCGA-BR-4370-11A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa5ec30d-13d3-441c-befb-78f226a3e2c4

The open-access MAF lists 1,279 somatic variants for this specimen: 974 protein-altering or splice-affecting, 277 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 651, Silent 277, Frame Shift Del 226, Frame Shift Ins 40, Nonsense Mutation 30, Intron 13, Splice Site 11, In Frame Del 8, Splice Region 7, RNA 6, 5'Flank 5, 3'UTR 2.

Variants (750 of 1,279; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- ARHGEF9 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 16/106 reads (15%) | catalogued as rs1135401795, COSV53636533; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.6259G>A p.G2087R | Missense Mutation (SNP) | VAF 43/215 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1553153748, COSV61371196, COSV61381160; ClinVar: other; called by muse, mutect2, varscan2
- BBS12 | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 63/291 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as rs776730549, CM104181, COSV58561688; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CFTR | c.3988_3989del p.Q1330Vfs*6 | Frame Shift Del (DEL) | VAF 36/258 reads (14%) | catalogued as rs1057516457; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- EFEMP1 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs121434491, CM990504, COSV62615573; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 104/543 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, varscan2
- GNPTAB | c.2693del p.K898Sfs*13 | Frame Shift Del (DEL) | VAF 93/422 reads (22%) | catalogued as rs281864999, CD090839; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- HNF1A | c.864del p.P291Qfs*51 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs762703502, CM1412341, CX035684, COSV104379772; ClinVar: pathogenic; called by mutect2, varscan2
- LDLR | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs879254657, CM0910341, COSV52942410; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- LPIN2 | c.2201C>T p.S734L | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs80338807, CM052249, COSV55238585; ClinVar: pathogenic; called by muse, varscan2
- LTBP3 | c.2216del p.G739Afs*7 | Frame Shift Del (DEL) | VAF 16/73 reads (22%) | catalogued as rs752375653, CD153951; ClinVar: pathogenic; called by mutect2, pindel
- MLH1 | c.1975C>T p.R659* | Nonsense Mutation (SNP) | VAF 23/101 reads (23%) | catalogued as rs63751310, CD962077, CM960973, COSV51616216, COSV51619199; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO6 | c.2751del p.K917Nfs*10 | Frame Shift Del (DEL) | VAF 26/140 reads (19%) | catalogued as rs551348450; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- PAFAH1B1 | c.1002+1G>A p.X334_splice | Splice Site (SNP) | VAF 32/157 reads (20%) | catalogued as rs113994203, CS003077, CS094808; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCYT1A | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs587777189, CM140074, COSV53056902; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAG1 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs758288006, CM1313163, COSV100201112, COSV55024544; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RP1 | c.3843del p.P1282Lfs*12 | Frame Shift Del (DEL) | VAF 79/540 reads (15%) | catalogued as rs769601671; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 13/87 reads (15%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- SMARCA4 | c.3694G>A p.G1232S | Missense Mutation (SNP) | VAF 54/260 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV60785813, COSV60799159; called by muse, varscan2
- ABCB8 | c.200G>A p.R67Q (on ENST00000297504 / NM_001282291.2; = p.R50Q on NM_007188.5) | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as rs375303002, COSV52503408, COSV52505170; called by muse, mutect2, varscan2
- ABCB9 | c.509C>A p.S170Y | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV54890935; called by muse, mutect2, varscan2
- ABCC6 | c.2960G>A p.R987H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374113337; called by muse, mutect2, varscan2
- ABCD1 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.87); catalogued as COSV54384008, COSV99497984; called by muse, mutect2, varscan2
- ABCF1 | c.1902C>A p.Y634* (on ENST00000326195 / NM_001025091.2; = p.Y596* on NM_001090.3) | Nonsense Mutation (SNP) | VAF 59/404 reads (15%) | catalogued as COSV58228553; called by muse, mutect2, varscan2
- ABHD17C | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as rs1342510818, COSV51917047; called by muse, mutect2, varscan2
- ABHD4 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.935); catalogued as rs752463205, COSV53529501; called by muse, mutect2, varscan2
- ABLIM1 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 47/223 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1003206870, COSV53302970; called by muse, mutect2, varscan2
- AC004922.1 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.575); catalogued as rs759358554, COSV53556096; called by mutect2, varscan2
- AC005324.2 | c.518A>G p.E173G | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV60886353; called by muse, mutect2, varscan2
- AC013489.1 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.356); catalogued as rs745794211, COSV51550752; called by muse, mutect2, varscan2
- ACADSB | c.1087T>C p.F363L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV62550534; called by muse, mutect2
- ACAP1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.7); catalogued as rs765783272, COSV50134614; called by muse, mutect2, varscan2
- ACP2 | c.436A>G p.I146V | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV57042108; called by muse, mutect2, varscan2
- ACSM3 | c.1103C>T p.T368M | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs748181119, COSV55500702; called by muse, mutect2, varscan2
- ACSM4 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770864463, COSV68067391; called by muse, mutect2
- ACTL7B | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV65927132; called by muse, mutect2, varscan2
- ACTRT2 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs374908751; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 92/220 reads (42%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM2 | c.1213-1G>T p.X405_splice | Splice Site (SNP) | VAF 57/369 reads (15%) | catalogued as COSV55860437; called by muse, mutect2, varscan2
- ADAM22 | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs772475954, COSV55973466; called by muse, mutect2
- ADAM7 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs746112199, COSV51537523, COSV51541741; called by muse, mutect2, varscan2
- ADAMTS10 | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.595); catalogued as rs782813134, COSV54353240; called by muse, mutect2
- ADCY7 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs141967597; called by muse, mutect2, varscan2
- ADCY8 | c.3500C>T p.T1167M | Missense Mutation (SNP) | VAF 33/249 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1356343883, COSV53897190; called by muse, mutect2, varscan2
- ADGRG1 | c.621G>A p.Q207= | Splice Region (SNP) | VAF 68/363 reads (19%) | catalogued as rs202000184, COSV65635391; called by muse, mutect2, varscan2
- ADGRL3 | c.1303G>A p.V435M (on ENST00000506720 / NM_001322402.2; = p.V367M on NM_015236.6) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72267499; called by muse, mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 38/229 reads (17%) | catalogued as rs761350619; called by mutect2, varscan2
- AFM | c.443G>A p.C148Y | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56919566; called by muse, mutect2
- AGO2 | c.2416G>A p.A806T | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55046318; called by muse, mutect2
- AGRP | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs370523045; called by muse, mutect2, varscan2
- AHNAK | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1331302779, COSV99948037; called by muse, mutect2, varscan2
- AIF1 | c.364C>A p.L122M | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.999); catalogued as COSV61962271; called by muse, mutect2
- AKAP13 | c.8207G>T p.R2736L (on ENST00000394518 / NM_007200.5; = p.R2740L on NM_006738.6) | Missense Mutation (SNP) | VAF 72/450 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV63452754, COSV63460008; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 12/87 reads (14%) | catalogued as COSV62339755; called by mutect2, varscan2
- ALDH1A1 | c.750T>C p.V250= | Splice Region (SNP) | VAF 29/145 reads (20%) | catalogued as COSV99921442; called by muse, mutect2, varscan2
- ALDH1A2 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 62/340 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51079346; called by muse, varscan2
- ALDH1L2 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 87/236 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.787); catalogued as rs199595605, COSV51554530; called by muse, mutect2, varscan2
- ALMS1 | c.7532G>A p.R2511Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs772807204, COSV52506804; called by muse, mutect2, varscan2
- ALPK2 | c.1067del p.L356Yfs*2 | Frame Shift Del (DEL) | VAF 40/197 reads (20%) | catalogued as rs756508755; called by mutect2, pindel, varscan2
- AMOT | c.1412G>A p.R471H (on ENST00000371959 / NM_001113490.1; = p.R62H on NM_133265.3) | Missense Mutation (SNP) | VAF 75/325 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1260955184, COSV59062004; called by muse, mutect2, varscan2
- ANK3 | c.9349del p.I3117Sfs*2 | Frame Shift Del (DEL) | VAF 76/446 reads (17%) | catalogued as rs370637835; called by mutect2, varscan2
- ANK3 | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 23/141 reads (16%) | catalogued as COSV55050843; called by muse, mutect2, varscan2
- ANKLE2 | c.2603C>T p.S868L | Missense Mutation (SNP) | VAF 111/480 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs200743167, COSV63294540, COSV63294600; called by muse, mutect2, varscan2
- ANKRD11 | c.776A>G p.N259S | Missense Mutation (SNP) | VAF 52/288 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV56358335; called by mutect2, varscan2
- ANKRD27 | c.1880C>T p.S627L | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs199608650, COSV60129563; called by muse, mutect2, varscan2
- ANKRD49 | c.258+13del | Splice Region (DEL) | VAF 45/136 reads (33%) | catalogued as rs750258320; called by mutect2, varscan2
- AP2A2 | c.1490A>G p.K497R | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV59959079; called by muse, mutect2, varscan2
- AP4M1 | c.689T>C p.L230S | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV57995111; called by muse, mutect2, varscan2
- APCDD1L | c.1447A>G p.I483V | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64485914; called by muse, mutect2, varscan2
- APOBEC3G | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs756302637, COSV68470165; called by muse, mutect2, varscan2
- APRT | c.394A>G p.T132A | Missense Mutation (SNP) | VAF 74/376 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51936401; called by muse, mutect2, varscan2
- ARCN1 | c.504G>T p.Q168H | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.336); catalogued as COSV50614644; called by muse, varscan2
- ARF1 | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.993); catalogued as COSV55254451; called by muse, varscan2
- ARF1 | c.323T>C p.M108T | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs901254200, COSV55254462; called by muse, varscan2
- ARFGEF1 | c.4033C>T p.R1345* | Nonsense Mutation (SNP) | VAF 15/112 reads (13%) | catalogued as rs146133956, COSV51605657; called by muse, varscan2
- ARHGAP25 | c.368G>A p.R123H (on ENST00000409202 / NM_001007231.3; = p.R116H on NM_014882.3) | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs1247374187, COSV54900641; called by muse, mutect2, varscan2
- ARHGAP25 | c.614A>G p.D205G (on ENST00000409202 / NM_001007231.3; = p.D197G on NM_014882.3) | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.802); catalogued as COSV54900665; called by muse, mutect2, varscan2
- ARHGAP28 | c.1748T>C p.L583S (on ENST00000383472 / NM_001366230.1; = p.L424S on NM_001010000.3) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51634847; called by muse, mutect2
- ARHGAP30 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761258662, COSV63515719; called by muse, mutect2, varscan2
- ARHGAP35 | c.3949G>A p.V1317M | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV68330140, COSV68330679; called by muse, mutect2, varscan2
- ARHGAP44 | c.2426C>T p.S809L | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); catalogued as rs1188383525, COSV52392284; called by muse, mutect2, varscan2
- ARHGEF11 | c.2569A>G p.M857V | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.163); catalogued as COSV59353261; called by muse, mutect2
- ARHGEF15 | c.2458C>T p.R820C | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs752135781, COSV62724730; called by muse, mutect2, varscan2
- ARID1B | c.5974del p.V1992Wfs*16 | Frame Shift Del (DEL) | VAF 27/183 reads (15%) | catalogued as rs749055122; called by mutect2, pindel, varscan2
- ARID2 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV57600509; called by muse, mutect2, varscan2
- ARID2 | c.716A>T p.D239V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57600519; called by muse, mutect2, varscan2
- ARID5B | c.3026C>G p.A1009G | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV54415348; called by muse, varscan2
- ARRDC5 | c.817C>A p.L273M (on ENST00000381781; = p.L259M on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751160875, COSV67787854; called by muse, mutect2, varscan2
- ARSL | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV66965046; called by muse, mutect2, varscan2
- ASB16 | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV99518943; called by muse, mutect2, varscan2
- ASTN2 | c.2149C>T p.Q717* (on ENST00000313400 / NM_001365069.1; = p.Q666* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 26/161 reads (16%) | catalogued as COSV57765792; called by muse, mutect2, varscan2
- ATP8B1 | c.556T>C p.F186L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as COSV52174096; called by muse, mutect2
- ATXN10 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs888558149, COSV53295096; called by muse, mutect2, varscan2
- BAZ2A | c.3808C>A p.L1270M | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as COSV51634218; called by muse, mutect2
- BCL3 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 36/261 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.378); catalogued as rs775770878, COSV99378200; called by muse, mutect2, varscan2
- BCL6 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 53/260 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as rs776120197, COSV51650532; called by muse, mutect2, varscan2
- BCR | c.607C>A p.L203M | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100005942, COSV59929243; called by muse, mutect2, varscan2
- BEND3 | c.2330T>C p.L777P | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100944628; called by muse, mutect2, varscan2
- BEND5 | c.1052del p.K351Rfs*15 | Frame Shift Del (DEL) | VAF 66/291 reads (23%) | catalogued as rs756345162, COSV65718189; called by mutect2, varscan2
- BHLHE22 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV58861582; called by muse, mutect2
- BICDL1 | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs375419624, COSV57492919; called by muse, mutect2, varscan2
- BOD1L1 | c.6773C>T p.T2258M | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs746873993, COSV50008725; called by muse, mutect2, varscan2
- BPIFB6 | c.80G>A p.G27D | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.873); catalogued as rs1291326000, COSV62754790; called by muse, mutect2, varscan2
- BRAT1 | c.1394C>T p.T465M | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1021569403, COSV61394832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD4 | c.3844C>T p.R1282C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as rs750347317, COSV54584235; called by muse, mutect2
- BRF1 | c.1506G>T p.K502N | Missense Mutation (SNP) | VAF 80/360 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV59267352; called by muse, mutect2, varscan2
- BRF1 | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1044258239, COSV59267364; called by muse, mutect2, varscan2
- BRMS1L | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53762773; called by muse, mutect2, varscan2
- BRMS1L | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.626); catalogued as rs1237296431, COSV53762786; called by muse, mutect2, varscan2
- BRPF3 | c.3233A>T p.E1078V | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as COSV60206734; called by muse, mutect2, varscan2
- BRSK1 | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 57/152 reads (38%) | catalogued as rs746043904, COSV58665984; called by mutect2, varscan2
- BRWD3 | c.3082C>T p.P1028S | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV64745970; called by muse, mutect2, varscan2
- BTBD17 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1451851946, COSV64729494; called by muse, mutect2, varscan2
- BUD13 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1017684654, COSV52767746; called by muse, mutect2, varscan2
- BUD23 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs141991727; called by muse, mutect2, varscan2
- C16orf70 | c.1230del p.R411Gfs*6 | Frame Shift Del (DEL) | VAF 38/291 reads (13%) | catalogued as rs539297455, COSV54625370; called by mutect2, pindel, varscan2
- C19orf44 | c.376G>A p.G126S | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54169079; called by muse, mutect2, varscan2
- C5 | c.4432C>T p.R1478W | Missense Mutation (SNP) | VAF 48/257 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs138933092; called by muse, mutect2, varscan2
- C5orf22 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1326620474, COSV57597891; called by muse, mutect2, varscan2
- C6orf118 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs781300980, COSV57813918; called by muse, mutect2, varscan2
- C8orf74 | c.436A>G p.M146V | Missense Mutation (SNP) | VAF 51/369 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58753859; called by muse, mutect2, varscan2
- CA9 | c.261G>T p.E87D | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as COSV65675239; called by muse, mutect2, varscan2
- CACNA1A | c.3603dup p.E1202Rfs*18 | Frame Shift Ins (INS) | VAF 22/144 reads (15%) | catalogued as rs747879307; called by mutect2, varscan2
- CACNA1C | c.6521C>T p.A2174V (on ENST00000399634 / NM_001167625.1; = p.A2103V on NM_000719.7) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.007); catalogued as rs1402303798, COSV59707496; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1E | c.2867G>A p.G956E | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV62387744; called by muse, mutect2, varscan2
- CAND2 | c.3304C>A p.L1102M (on ENST00000456430 / NM_001162499.2; = p.L985M on NM_012298.3) | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV55988645; called by muse, mutect2, varscan2
- CANX | c.1305del p.F435Lfs*12 | Frame Shift Del (DEL) | VAF 22/174 reads (13%) | catalogued as rs760711956; called by mutect2, varscan2
- CAPSL | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs754628339, COSV68437645; called by muse, mutect2, varscan2
- CARMIL2 | c.1897C>A p.L633M | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58024629; called by muse, mutect2, varscan2
- CATSPER2 | c.1255G>T p.E419* (on ENST00000321596 / NM_001282309.3; = p.E421* on NM_172095.4) | Nonsense Mutation (SNP) | VAF 29/126 reads (23%) | catalogued as COSV100390812; called by muse, mutect2, varscan2
- CCDC14 | c.761C>G p.A254G (on ENST00000488653; = p.A206G on NM_022757.5) | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV59943755; called by muse, mutect2, varscan2
- CCDC186 | c.2648G>A p.R883H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs188209343, COSV100991122; called by muse, mutect2, varscan2
- CCDC66 | c.1900G>T p.E634* (on ENST00000394672 / NM_001353147.1; = p.E600* on NM_001012506.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 27/110 reads (25%) | catalogued as COSV58302627; called by muse, mutect2, varscan2
- CCDC85A | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV68149271; called by muse, mutect2
- CCDC9B | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.066); catalogued as COSV66875091; called by muse, mutect2, varscan2
- CD109 | c.2407G>T p.G803C | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); catalogued as rs776569949, COSV54647610; called by muse, mutect2, varscan2
- CD5 | c.232T>C p.S78P | Missense Mutation (SNP) | VAF 62/407 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.474); catalogued as COSV61718090; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 23/170 reads (14%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDCA2 | c.3041G>T p.R1014M | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV57945224; called by muse, mutect2, varscan2
- CDH8 | c.1763G>A p.S588N | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV54858400; called by muse, mutect2, varscan2
- CDK11A | c.1507G>A p.V503M (on ENST00000378633 / NM_001313896.2; = p.V500M on NM_024011.4) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749952146, COSV99319321; called by muse, mutect2
- CDK5RAP2 | c.998del p.K333Rfs*76 | Frame Shift Del (DEL) | VAF 27/132 reads (20%) | catalogued as rs973156155; called by mutect2, pindel, varscan2
- CDYL2 | c.782C>T p.T261M | Missense Mutation (SNP) | VAF 37/233 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778603352, COSV73653964; called by muse, mutect2, varscan2
- CELF4 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs1340223204, COSV100611728; called by muse, mutect2
- CELSR1 | c.5824G>A p.G1942R | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs1161145438, COSV53086657; called by muse, mutect2, varscan2
- CEMIP2 | c.3161G>A p.R1054Q | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs760499289, COSV65484436; called by muse, mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 14/90 reads (16%) | catalogued as rs1325731082; called by mutect2, pindel
- CENPF | c.4151T>C p.L1384S | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as rs1007161686, COSV65273766; called by muse, mutect2, varscan2
- CENPJ | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs745427182, COSV67883230; called by muse, mutect2, varscan2
- CEP131 | c.2834G>A p.R945Q (on ENST00000269392 / NM_001319228.2; = p.R942Q on NM_014984.4) | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.34); catalogued as rs111464253, COSV53951663; called by muse, mutect2, varscan2
- CEP192 | c.2362del p.T788Qfs*40 | Frame Shift Del (DEL) | VAF 17/120 reads (14%) | catalogued as COSV58068098; called by mutect2, pindel, varscan2
- CEP76 | c.1530del p.P512Hfs*12 | Frame Shift Del (DEL) | VAF 40/238 reads (17%) | catalogued as COSV50867563; called by mutect2, varscan2
- CFAP69 | c.2822C>T p.T941M | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); catalogued as rs376414901; called by muse, mutect2
- CFHR5 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV56820202; called by muse, mutect2, varscan2
- CHD1L | c.2525G>A p.R842H | Missense Mutation (SNP) | VAF 72/302 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782473109, COSV63613393; called by muse, varscan2
- CHD9 | c.2818G>T p.G940W | Missense Mutation (SNP) | VAF 65/368 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54609055; called by muse, mutect2, varscan2
- CHMP6 | c.578G>T p.R193M | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV57327166; called by muse, mutect2
- CHRNA4 | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs796052323, COSV64718969; called by muse, mutect2, varscan2
- CHST6 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121917826, CM040695, COSV59999822; called by muse, mutect2, varscan2
- CLASP1 | c.3692del p.G1231Vfs*4 | Frame Shift Del (DEL) | VAF 16/126 reads (13%) | catalogued as rs749719822, COSV99752279; called by mutect2, varscan2
- CLEC2D | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.326); catalogued as rs1173742081, COSV51993151; called by muse, mutect2, varscan2
- CLGN | c.668A>T p.D223V | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57773913; called by muse, mutect2, varscan2
- CLK3 | c.668G>A p.R223Q (on ENST00000395066 / NM_001130028.1; = p.R75Q on NM_003992.4) | Missense Mutation (SNP) | VAF 85/377 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs146329671; called by muse, mutect2, varscan2
- CLMN | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs146706338; called by muse, mutect2, varscan2
- CMYA5 | c.8674T>C p.Y2892H | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV71404963; called by muse, mutect2, varscan2
- CNKSR2 | c.1051C>T p.L351F | Missense Mutation (SNP) | VAF 191/911 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV54252751; called by muse, mutect2, varscan2
- CNOT1 | c.2706del p.Q904Sfs*9 | Frame Shift Del (DEL) | VAF 66/372 reads (18%) | catalogued as rs1397135931, COSV55313852; called by mutect2, pindel, varscan2
- CNPY4 | c.41del p.L14Wfs*11 | Frame Shift Del (DEL) | VAF 31/158 reads (20%) | catalogued as rs1347948509; called by mutect2, varscan2
- COL1A2 | c.2465G>A p.R822H | Missense Mutation (SNP) | VAF 70/422 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1800240, COSV51955634; called by muse, mutect2, varscan2
- COL2A1 | c.4223A>G p.K1408R | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV61529278; called by muse, mutect2
- COL4A2 | c.4275dup p.G1426Rfs*30 | Frame Shift Ins (INS) | VAF 13/94 reads (14%) | catalogued as rs34603892; called by mutect2, varscan2
- COL5A1 | c.1480del p.D494Tfs*64 | Frame Shift Del (DEL) | VAF 23/203 reads (11%) | catalogued as CM128975; called by mutect2, pindel, varscan2
- COL6A3 | c.5744G>A p.R1915Q | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs374825188, COSV55079548; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COQ8A | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 44/264 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766101783, COSV62008244; called by muse, mutect2, varscan2
- CPSF6 | c.1519C>T p.R507* | Nonsense Mutation (SNP) | VAF 41/149 reads (28%) | catalogued as COSV57013477; called by muse, mutect2, varscan2
- CPT1A | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.416); catalogued as rs373015421; called by muse, mutect2
- CRTAC1 | c.611G>A p.G204D | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53999549; called by muse, mutect2, varscan2
- CRYBG1 | c.3379_3381del p.K1127del | In Frame Del (DEL) | VAF 28/174 reads (16%) | catalogued as rs760490539; called by pindel, varscan2
- CSPG4 | c.3101G>A p.R1034Q | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755806843, COSV57893023; called by muse, varscan2
- CSPG4 | c.3040G>A p.V1014M | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs925306142, COSV100413882, COSV57893036; called by muse, varscan2
- CTCFL | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 84/498 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54772324; called by muse, varscan2
- CTDSPL | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs868785872, COSV56201429; called by muse, varscan2
- CUL9 | c.2522C>T p.P841L | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs751085752, COSV52727058; called by muse, mutect2, varscan2
- CUX1 | c.1615C>T p.R539C (on ENST00000437600 / NM_181500.4; = p.R541C on NM_001913.5) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs782760993, COSV52927056; called by muse, mutect2, varscan2
- CXXC5 | c.898A>G p.K300E | Missense Mutation (SNP) | VAF 36/362 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV56793447; called by muse, mutect2, varscan2
- CYFIP2 | c.3299G>A p.R1100H (on ENST00000616178 / NM_001291722.2; = p.R1075H on NM_014376.4) | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV59033324; called by muse, mutect2, varscan2
- CYP11B1 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs144224988; called by muse, mutect2, varscan2
- CYP21A2 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781074931, CM101303, COSV64476331; called by muse, mutect2, varscan2
- DAG1 | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767440555, COSV58183441; called by muse, mutect2, varscan2
- DAGLA | c.1474C>T p.L492F | Missense Mutation (SNP) | VAF 93/712 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57195092; called by muse, varscan2
- DBX2 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs760536409, COSV60337045; called by muse, mutect2, varscan2
- DCBLD2 | c.366T>A p.D122E | Missense Mutation (SNP) | VAF 53/313 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.378); catalogued as COSV58788544; called by muse, mutect2, varscan2
- DDB1 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 80/491 reads (16%) | catalogued as rs780534106, COSV57101576; called by muse, mutect2, varscan2
- DDX60 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs758196490, COSV67094909; called by muse, mutect2, varscan2
- DEPDC7 | c.143C>T p.T48I (on ENST00000241051 / NM_001077242.2; = p.T39I on NM_139160.2) | Missense Mutation (SNP) | VAF 60/302 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as COSV53806461; called by muse, mutect2, varscan2
- DEPP1 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as rs141296778; called by muse, mutect2, varscan2
- DLL4 | c.1120G>A p.G374R | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51061532; called by muse, mutect2, varscan2
- DNAH7 | c.4805G>A p.R1602H | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758390184, COSV56758146; called by muse, mutect2, varscan2
- DNAJC17 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 84/448 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.728); catalogued as rs1368283580, COSV55024564; called by muse, mutect2, varscan2
- DNAJC6 | c.1583T>G p.F528C | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54772600; called by muse, mutect2, varscan2
- DNHD1 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs746591414, COSV54432634; called by muse, mutect2, varscan2
- DNMT1 | c.1246C>T p.H416Y | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.99); PolyPhen benign (0.015); catalogued as rs181300723, COSV61577805; called by muse, mutect2, varscan2
- DOCK1 | c.2210A>C p.K737T | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV54734854; called by muse, mutect2, varscan2
- DOK2 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as COSV52388053; called by muse, mutect2
- DPAGT1 | c.698del p.F233Sfs*28 | Frame Shift Del (DEL) | VAF 55/258 reads (21%) | catalogued as rs35482889; called by mutect2, varscan2
- DPYSL4 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149476256; called by muse, mutect2, varscan2
- DSCAM | c.5978T>C p.L1993P | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV68024060; called by muse, varscan2
- DSCAM | c.2432C>T p.A811V | Missense Mutation (SNP) | VAF 39/211 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV68020093; called by muse, mutect2, varscan2
- DSG3 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.806); catalogued as rs772960249, COSV57124134; called by muse, mutect2, varscan2
- DST | c.1793T>G p.L598* (on ENST00000361203 / NM_001374722.1; = p.L272* on NM_001723.6) | Nonsense Mutation (SNP) | VAF 19/114 reads (17%) | catalogued as COSV55006093; called by muse, mutect2, varscan2
- DUOX2 | c.1312C>A p.L438M | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66531353; called by muse, mutect2, varscan2
- DUSP21 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 48/261 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.383); catalogued as rs867156846, COSV100173619, COSV59133623; called by muse, varscan2
- DYNC2I1 | c.3178C>T p.P1060S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV68104203; called by muse, mutect2
- EBF1 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58166381, COSV58173197; called by muse, mutect2, varscan2
- EFCAB13 | c.190dup p.I64Nfs*3 | Frame Shift Ins (INS) | VAF 12/61 reads (20%) | catalogued as rs995188950; called by mutect2, varscan2
- EIF3G | c.580_582del p.E194del | In Frame Del (DEL) | VAF 32/208 reads (15%) | catalogued as rs1237541686; called by mutect2, pindel, varscan2
- EIF5A | c.155G>A p.G52D | Missense Mutation (SNP) | VAF 11/218 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV59748296; called by muse, mutect2
- EIF5AL1 | c.155G>A p.G52D | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1428113988, COSV101592806; called by mutect2, varscan2
- EIF5B | c.3012+1G>A p.X1004_splice | Splice Site (SNP) | VAF 37/216 reads (17%) | catalogued as COSV56812050; called by muse, mutect2, varscan2
- ENGASE | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 45/267 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1032810670, COSV56136159; called by muse, mutect2, varscan2
- ENO3 | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 50/310 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1379047673, COSV52776724; called by muse, mutect2, varscan2
- EPHA10 | c.2604del p.R869Gfs*10 | Frame Shift Del (DEL) | VAF 21/106 reads (20%) | catalogued as rs1449193125; called by mutect2, pindel, varscan2
- EPHB6 | c.1517C>T p.T506M | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747288408, COSV63891223, COSV63892212; called by muse, mutect2
- EPX | c.842G>A p.C281Y | Missense Mutation (SNP) | VAF 49/325 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56595696; called by muse, mutect2, varscan2
- ERBB3 | c.383G>A p.S128N | Missense Mutation (SNP) | VAF 118/300 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.052); catalogued as COSV57249629, COSV57265777; called by muse, mutect2, varscan2
- EVPL | c.4082T>C p.L1361P | Missense Mutation (SNP) | VAF 57/292 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56909076; called by muse, mutect2, varscan2
- EVX2 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775266360, COSV57962874; called by muse, mutect2, varscan2
- EXOC3L1 | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV52045626, COSV52048160; called by muse, mutect2, varscan2
- EXOC4 | c.440G>A p.S147N | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.542); catalogued as COSV54091153; called by muse, mutect2, varscan2
- EXOSC2 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as rs1227420765, COSV64910501; called by muse, mutect2, varscan2
- EXPH5 | c.4166T>C p.L1389S | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.177); catalogued as COSV56200483; called by muse, mutect2, varscan2
- FAM131A | c.634G>A p.D212N (on ENST00000310585; = p.D243N on NM_144635.5) | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.69); catalogued as rs373533464; called by muse, varscan2
- FAM172A | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 13/117 reads (11%) | catalogued as COSV67936141; called by muse, mutect2, varscan2
- FAM221A | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.085); catalogued as rs1295927090, COSV100794345; called by muse, mutect2, varscan2
- FAM76B | c.556C>T p.H186Y | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.204); catalogued as COSV62556251; called by muse, mutect2, varscan2
- FANCM | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.107); catalogued as COSV53531707; called by muse, mutect2, varscan2
- FAP | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.446); catalogued as rs751170815, COSV51860572; called by muse, mutect2, varscan2
- FARP1 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.771); catalogued as rs377656768; called by muse, mutect2
- FAXC | c.1202A>C p.D401A | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.086); catalogued as COSV67601839, COSV67602332; called by muse, mutect2, varscan2
- FBLN7 | c.931G>A p.V311M | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs546176669, COSV55615795; called by muse, mutect2, varscan2
- FBXL18 | c.1610C>T p.T537M | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370339712; called by muse, mutect2, varscan2
- FBXO22 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV57617060; called by muse, mutect2, varscan2
- FBXO46 | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58348173; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 44/240 reads (18%) | catalogued as rs748969702; called by mutect2, varscan2
- FIBCD1 | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as rs555984144, COSV53392957; called by muse, mutect2, varscan2
- FIP1L1 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1355761572, COSV60995018; called by muse, mutect2
- FIP1L1 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 49/254 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.188); catalogued as rs749819796, COSV55783791; called by muse, mutect2, varscan2
- FLG | c.11744C>A p.S3915Y | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV64239494, COSV64249553; called by muse, mutect2, varscan2
- FLNA | c.2527del p.A843Lfs*33 | Frame Shift Del (DEL) | VAF 49/270 reads (18%) | catalogued as COSV61053015; called by mutect2, pindel, varscan2
- FMNL3 | c.2759G>A p.R920Q | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as rs779542588, COSV53300091; called by muse, mutect2, varscan2
- FNBP4 | c.1429C>T p.R477* | Nonsense Mutation (SNP) | VAF 7/124 reads (6%) | catalogued as COSV55446894; called by muse, mutect2
- FOLR3 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs374758856; called by muse, mutect2, varscan2
- FOXD4L4 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 26/283 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs1167414287; called by muse, mutect2, varscan2
- FOXE1 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768174425, COSV64300304; called by muse, mutect2, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 30/170 reads (18%) | catalogued as rs760347049; called by mutect2, pindel, varscan2
- FOXP4 | c.1546C>T p.R516C (on ENST00000307972 / NM_001012426.1; = p.R503C on NM_138457.3) | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57219058; called by muse, mutect2, varscan2
- FRYL | c.2534C>T p.P845L | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV51943834; called by muse, mutect2, varscan2
- FSTL5 | c.695A>G p.H232R | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100053272, COSV60187777; called by muse, mutect2, varscan2
- FUZ | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs574943060, COSV58241119; called by muse, mutect2
- FZD6 | c.1824del p.R609Gfs*2 | Frame Shift Del (DEL) | VAF 22/106 reads (21%) | catalogued as COSV62472526; called by mutect2, pindel, varscan2
- GABRB2 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV50906012; called by muse, mutect2, varscan2
- GAL3ST1 | c.905T>C p.M302T | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.022); catalogued as COSV58892266; called by muse, mutect2, varscan2
- GALNT17 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 88/670 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs974898586, COSV61155556; called by muse, varscan2
- GALNT18 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs377131654; called by muse, mutect2, varscan2
- GANC | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 20/142 reads (14%) | PolyPhen probably damaging (0.993); catalogued as rs753728748, COSV58808181; called by muse, mutect2, varscan2
- GAREM1 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1231949829, COSV52507627; called by muse, mutect2, varscan2
- GAS1 | c.623A>G p.E208G | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV53926802; called by muse, mutect2, varscan2
- GATA3 | c.708dup p.S237Qfs*66 | Frame Shift Ins (INS) | VAF 18/116 reads (16%) | catalogued as rs771019738, COSV60521878; called by mutect2, varscan2
- GBF1 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 59/237 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770542755, COSV64143899; called by muse, mutect2, varscan2
- GBX2 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 39/229 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as COSV60445017; called by muse, mutect2, varscan2
- GCC1 | c.1940C>T p.A647V | Missense Mutation (SNP) | VAF 41/264 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs777223414, COSV58462157; called by muse, mutect2, varscan2
- GFOD1 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as rs767747080, COSV64954491; called by muse, varscan2
- GFOD2 | c.868G>T p.G290* | Nonsense Mutation (SNP) | VAF 29/133 reads (22%) | catalogued as COSV52057477; called by muse, mutect2, varscan2
- GGT1 | c.1436C>T p.T479M | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752649541, COSV50639091; called by muse, mutect2, varscan2
- GLB1L3 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs750384439, COSV66281951; called by muse, mutect2, varscan2
- GLRB | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 53/214 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1560967306, COSV52415127; called by muse, mutect2, varscan2
- GLYR1 | c.1567A>G p.M523V | Missense Mutation (SNP) | VAF 48/262 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as rs1468781047, COSV58926418; called by muse, mutect2, varscan2
- GNAI3 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 71/309 reads (23%) | catalogued as rs766202043, COSV63983494; called by muse, mutect2, varscan2
- GNAZ | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs765527032, COSV50737426; called by muse, mutect2, varscan2
- GPR160 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs372339784, COSV63472725; called by muse, mutect2, varscan2
- GPR62 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as COSV59054157; called by muse, mutect2, varscan2
- GPRASP1 | c.3623C>T p.P1208L | Missense Mutation (SNP) | VAF 46/259 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64355208; called by muse, mutect2, varscan2
- GPRC6A | c.2432C>T p.P811L | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as rs777781673, COSV59951433; called by muse, mutect2
- GPS1 | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs767711993, COSV57648287; called by muse, mutect2, varscan2
- GRIA1 | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 49/261 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.218); catalogued as COSV53596876; called by muse, mutect2, varscan2
- GRIA2 | c.573G>A p.M191I | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52386581; called by muse, varscan2
- GRIA2 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 52/278 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52386592; called by muse, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 34/244 reads (14%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIN2D | c.1734C>T p.L578= | Splice Region (SNP) | VAF 8/98 reads (8%) | catalogued as rs1407595627, COSV54377886; called by muse, mutect2
- GTF3C4 | c.1691del p.K564Rfs*18 | Frame Shift Del (DEL) | VAF 42/294 reads (14%) | catalogued as rs1241168444, COSV64645321; called by mutect2, pindel, varscan2
- GUCY2D | c.1919G>C p.W640S | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM116139, COSV54695503; called by muse, mutect2, varscan2
- H2AC11 | c.355A>C p.K119Q | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as COSV60361927; called by muse, mutect2, varscan2
- HAGH | c.638del p.P213Rfs*61 | Frame Shift Del (DEL) | VAF 16/101 reads (16%) | catalogued as rs751524326; called by mutect2, pindel, varscan2
- HAO1 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as rs767887781, COSV66491546; called by muse, mutect2, varscan2
- HARS1 | c.389A>G p.D130G | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56906219; called by muse, mutect2, varscan2
- HECTD4 | c.13100dup p.D4368Rfs*44 | Frame Shift Ins (INS) | VAF 85/230 reads (37%) | catalogued as rs746492036; called by mutect2, varscan2
- HECTD4 | c.10063G>A p.A3355T | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs747606994, COSV66389337, COSV66389907; called by muse, mutect2, varscan2
- HELLS | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT tolerated (0.9); PolyPhen benign (0.017); catalogued as rs1279408343, COSV53295668; called by muse, mutect2, varscan2
- HELQ | c.1105G>T p.A369S | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55024665; called by muse, varscan2
- HERC1 | c.7703G>A p.R2568Q | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.968); catalogued as rs1482730191, COSV71246936; called by muse, mutect2, varscan2
- HERC2 | c.5012G>T p.G1671V | Missense Mutation (SNP) | VAF 70/373 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55316037; called by muse, mutect2, varscan2
- HIC1 | c.1792G>A p.G598S (on ENST00000322941 / NM_001098202.1; = p.G579S on NM_006497.4) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1244832850, COSV53965277; called by muse, mutect2, varscan2
- HIC2 | c.686del p.G229Afs*45 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs1218980629; called by mutect2, pindel, varscan2
- HILPDA | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 16/159 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV57556123; called by muse, mutect2
- HIPK3 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs556300403, COSV57561507; called by muse, mutect2, varscan2
- HJURP | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.234); catalogued as rs763383099, COSV64978652; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 16/92 reads (17%) | catalogued as rs761272507; called by mutect2, varscan2
- HMX2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60592534; called by muse, mutect2
- HNRNPM | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 52/514 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV57692103; called by muse, mutect2, varscan2
- HOXA2 | c.538C>A p.L180M | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56065739; called by muse, mutect2, varscan2
- HOXA9 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1252918425, COSV100604433; called by muse, mutect2, varscan2
- HRH1 | c.695C>A p.P232H | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.888); catalogued as COSV67955258; called by muse, mutect2, varscan2
- HSD3B7 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.652); catalogued as rs143419053; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSPA14 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1348700868, COSV65684157; called by muse, mutect2, varscan2
- HSPA9 | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as rs752447855, COSV51864062; called by muse, mutect2, varscan2
- HTR7 | c.1025C>A p.P342Q | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53284831; called by muse, mutect2, varscan2
- HTRA3 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369124292, COSV56470248; called by muse, mutect2, varscan2
- HTT | c.3670T>A p.S1224T | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.133); catalogued as COSV61859777; called by muse, mutect2, varscan2
- IBTK | c.3638del p.K1213Sfs*50 | Frame Shift Del (DEL) | VAF 12/77 reads (16%) | catalogued as rs757667533; called by mutect2, pindel, varscan2
- IFIT1B | c.182T>C p.V61A | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV65663317; called by muse, mutect2, varscan2
- IFT172 | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs777914345, COSV53131745; called by muse, mutect2, varscan2
- IGF2BP2 | c.1793G>A p.S598N | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.15); catalogued as COSV60484471, COSV60487756; called by muse, mutect2, varscan2
- IGHV3-13 | c.256T>C p.F86L | Missense Mutation (SNP) | VAF 61/270 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.603); catalogued as rs1555437106; called by muse, mutect2, varscan2
- IGHV3-15 | c.105del p.S36Pfs*18 | Frame Shift Del (DEL) | VAF 19/166 reads (11%) | catalogued as rs781984574; called by mutect2, pindel, varscan2
- IKBKB | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 31/261 reads (12%) | catalogued as COSV60596529; called by muse, mutect2, varscan2
- IL12RB1 | c.1217G>T p.G406V | Missense Mutation (SNP) | VAF 51/356 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as rs199504990, COSV59096557; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IMPA1 | c.424A>G p.N142D | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.085); catalogued as COSV56270740; called by muse, mutect2, varscan2
- INTS11 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV60087861; called by muse, mutect2, varscan2
- INTS3 | c.2721-1G>A p.X907_splice | Splice Site (SNP) | VAF 41/187 reads (22%) | catalogued as COSV55162845; called by muse, mutect2, varscan2
- INTS7 | c.200A>C p.K67T | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV65344023; called by muse, mutect2, varscan2
- INTS8 | c.837del p.F279Lfs*6 | Frame Shift Del (DEL) | VAF 28/210 reads (13%) | catalogued as COSV58249114; called by mutect2, pindel, varscan2
- IPO13 | c.2351G>A p.R784K | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV64893098; called by muse, mutect2, varscan2
- IPO5 | c.2099C>T p.T700I | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.119); catalogued as COSV55152587; called by muse, mutect2, varscan2
- IQCE | c.1616del p.K539Rfs*25 | Frame Shift Del (DEL) | VAF 19/133 reads (14%) | catalogued as rs759821884; called by mutect2, pindel*, varscan2
- IRF2 | c.174G>T p.W58C | Missense Mutation (SNP) | VAF 53/300 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66929082; called by muse, varscan2
- IRF9 | c.188C>A p.A63E | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60702947; called by muse, mutect2, varscan2
- IRX6 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV51859171; called by muse, mutect2, varscan2
- ITFG1 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.187); catalogued as COSV57746357; called by muse, mutect2, varscan2
- ITFG2 | c.431T>C p.V144A | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57389366, COSV57389777; called by muse, mutect2, varscan2
- ITGA9 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.418); catalogued as rs754655531, COSV53239481; called by muse, mutect2, varscan2
- ITPR3 | c.7225G>T p.A2409S | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.05); catalogued as COSV65291013; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 20/124 reads (16%) | catalogued as rs755650243; called by mutect2, varscan2
- JAM3 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV54451704; called by muse, mutect2, varscan2
- JPH1 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.179); catalogued as rs376014048, COSV60609890; called by muse, mutect2, varscan2
- JPH3 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV52466091; called by muse, mutect2, varscan2
- JPT1 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs868058942, COSV59173129; called by muse, mutect2, varscan2
- KANK1 | c.3736C>T p.R1246W | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs369238209; called by muse, mutect2, varscan2
- KANSL1 | c.3194G>A p.R1065H (on ENST00000574590 / NM_001193465.2; = p.R1066H on NM_015443.4) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs368475798, COSV52237183; called by muse, mutect2, varscan2
- KCNA5 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs747143051, COSV52904171; called by muse, mutect2, varscan2
- KCNF1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs767981110, COSV54462647; called by muse, mutect2, varscan2
- KCNH8 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1379582412, COSV60460065; called by muse, mutect2, varscan2
- KCNK12 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV100010118; called by muse, mutect2
- KCNK17 | c.503del p.G168Afs*61 | Frame Shift Del (DEL) | VAF 28/209 reads (13%) | catalogued as COSV64685346; called by mutect2, pindel, varscan2
- KCNK9 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs775502608, COSV57279793; called by muse, mutect2, varscan2
- KCNS2 | c.1154C>T p.T385M | Missense Mutation (SNP) | VAF 49/308 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as rs201873843, COSV54637904; called by muse, mutect2, varscan2
- KCNU1 | c.2129A>T p.Y710F | Missense Mutation (SNP) | VAF 97/646 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV67754537; called by muse, mutect2, varscan2
- KDM3B | c.2813G>A p.R938H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58687612, COSV58694972; called by muse, mutect2
- KDM4B | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50208658; called by muse, mutect2, varscan2
- KIAA0100 | c.4721G>A p.R1574Q | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV66491576; called by muse, mutect2, varscan2
- KIAA1109 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1235726317, COSV52661055, COSV99149397; called by muse, mutect2, varscan2
- KIAA1109 | c.6283C>T p.R2095C | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs528587230, COSV52667344; called by muse, mutect2, varscan2
- KIAA1109 | c.9823C>G p.P3275A | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV52667372; called by muse, mutect2, varscan2
- KIAA1328 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV54450867; called by muse, mutect2, varscan2
- KIDINS220 | c.1960dup p.T654Nfs*28 | Frame Shift Ins (INS) | VAF 24/112 reads (21%) | catalogued as rs1290411154; called by mutect2, varscan2
- KIF13B | c.2886C>A p.N962K | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.113); catalogued as COSV72954310; called by muse, mutect2, varscan2
- KIF26B | c.3199del p.R1067Gfs*65 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | catalogued as COSV63639593; called by mutect2, pindel, varscan2
- KLF15 | c.662T>C p.L221P | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56179741; called by muse, mutect2, varscan2
- KLHL22 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1273833949, COSV61020365; called by muse, mutect2, varscan2
- KLK6 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs200194649, COSV59565296; called by muse, varscan2
- KMT2D | c.15460C>T p.R5154W | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768551828, COSV56424929; called by muse, mutect2, varscan2
- KRT3 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.707); catalogued as rs370673258; called by muse, mutect2, varscan2
- KRT31 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs374406520; called by muse, mutect2, varscan2
- KRT77 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 350/857 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as rs756106631, COSV59239138; called by muse, mutect2, varscan2
- KRTAP10-2 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs368800676; called by muse, mutect2, varscan2
- KRTAP12-2 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.072); catalogued as COSV59956910; called by muse, mutect2, varscan2
- KRTAP24-1 | c.242G>A p.C81Y | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV61089219; called by muse, mutect2, varscan2
- KRTAP5-1 | c.257dup p.C89Lfs*139 | Frame Shift Ins (INS) | VAF 32/191 reads (17%) | catalogued as COSV66298816; called by mutect2, varscan2
- L1CAM | c.2239del p.Q747Rfs*104 | Frame Shift Del (DEL) | VAF 21/110 reads (19%) | catalogued as rs782198738, CM1514439; called by mutect2, pindel, varscan2
- L3HYPDH | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1380085377, COSV54198906; called by muse, mutect2
- LAMC1 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 45/268 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51134637; called by muse, mutect2, varscan2
- LAMC1 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 79/523 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as rs150210600; called by muse, mutect2, varscan2
- LARP1 | c.906dup p.T303Hfs*19 (on ENST00000518297 / NM_033551.3; = p.T226Hfs*19 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 65/540 reads (12%) | catalogued as rs769338468; called by mutect2, varscan2
- LBX1 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV64621601; called by muse, varscan2
- LCE1E | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 78/448 reads (17%) | catalogued as rs528518200, COSV100908514; called by muse, mutect2, varscan2
- LDB3 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780200228, COSV53939584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LIPA | c.185G>A p.C62Y | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV51078456; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 46/210 reads (22%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMTK2 | c.1664T>C p.L555S | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51993364; called by muse, mutect2, varscan2
- LONP2 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751260535, COSV53521495; called by muse, mutect2, varscan2
- LPAR3 | c.139del p.S47Lfs*9 | Frame Shift Del (DEL) | VAF 58/248 reads (23%) | catalogued as rs762083435; called by mutect2, varscan2
- LRFN3 | c.1762G>A p.G588S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs750877490, COSV55817293; called by muse, mutect2
- LRRC4C | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs754463669, COSV53422015; called by muse, mutect2, varscan2
- LRRIQ1 | c.4378T>A p.S1460T | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67828289; called by muse, mutect2, varscan2
- LRRN4CL | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs776870074, COSV54015066; called by muse, mutect2, varscan2
- MACO1 | c.306del p.F102Lfs*47 | Frame Shift Del (DEL) | VAF 26/142 reads (18%) | catalogued as rs752439249; called by mutect2, varscan2
- MAGEB2 | c.113C>A p.A38D | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.422); catalogued as COSV66780518; called by muse, mutect2, varscan2
- MAN2B2 | c.476C>T p.T159M | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs553296276, COSV53451824; called by muse, mutect2, varscan2
- MAN2C1 | c.2621G>C p.G874A | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51227425; called by muse, mutect2, varscan2
- MAP4K2 | c.1053G>A p.P351= | Splice Region (SNP) | VAF 40/217 reads (18%) | catalogued as rs150214987; called by muse, mutect2, varscan2
- MAP7D3 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 85/450 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs763827540, COSV60170488; called by muse, mutect2, varscan2
- MAPKBP1 | c.3982C>T p.P1328S (on ENST00000456763 / NM_001128608.2; = p.P1322S on NM_014994.3) | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV52959673; called by muse, mutect2, varscan2
- MARCHF5 | c.563G>T p.C188F | Missense Mutation (SNP) | VAF 154/876 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV62769397; called by muse, mutect2, varscan2
- MBD4 | c.939del p.E314Kfs*4 | Frame Shift Del (DEL) | VAF 99/256 reads (39%) | catalogued as rs558765093; called by mutect2, varscan2
- MBNL2 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.356); catalogued as rs148388439; called by muse, mutect2, varscan2
- MCEE | c.419del p.K140Rfs*6 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | catalogued as rs776473131; called by mutect2, varscan2
- MCM5 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs757968764, COSV53345645; called by muse, mutect2, varscan2
- MDGA1 | c.1213C>A p.L405M | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as COSV51793957; called by muse, mutect2, varscan2
- MDGA2 | c.2965G>A p.A989T (on ENST00000399232 / NM_001113498.2; = p.A691T on NM_182830.4) | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs1335431204, COSV62085097; called by muse, mutect2, varscan2
- MDH1 | c.760G>A p.V254I | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs749293863, COSV51862991, COSV51864469; called by muse, mutect2, varscan2
- MEGF8 | c.7459G>A p.V2487M (on ENST00000251268 / NM_001271938.2; = p.V2420M on NM_001410.3) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV52079504; called by muse, mutect2, varscan2
- MFHAS1 | c.3067C>T p.R1023* | Nonsense Mutation (SNP) | VAF 18/114 reads (16%) | catalogued as rs769753343, COSV52280907; called by muse, mutect2, varscan2
- MGAM | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.238); catalogued as rs371373847; called by muse, mutect2
- MIA3 | c.5059G>A p.V1687M | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.192); catalogued as rs760884535, COSV60511532; called by muse, mutect2, varscan2
- MICAL2 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764483530, COSV56318675; called by muse, mutect2, varscan2
- MINAR1 | c.224A>G p.N75S | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV59581878; called by muse, mutect2
- MLIP | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.134); catalogued as rs146529618; called by muse, mutect2
- MMP7 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs145006821; called by muse, mutect2, varscan2
- MMP9 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV63433920; called by muse, mutect2, varscan2
- MRGPRX2 | c.751A>G p.K251E | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV61674014; called by muse, mutect2, varscan2
- MRPL18 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs771806574, COSV51704532, COSV51704635; called by muse, mutect2, varscan2
- MS4A14 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as COSV100280523; called by muse, varscan2
- MSANTD2 | c.1408A>G p.T470A (on ENST00000374979 / NM_001308027.2; = p.T418A on NM_024631.4) | Missense Mutation (SNP) | VAF 68/369 reads (18%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs1057004307, COSV53448149; called by muse, mutect2, varscan2
- MSH6 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.315); catalogued as rs63750143, COSV52276698; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTOR | c.6577C>T p.R2193C | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63869686; called by muse, mutect2, varscan2
- MTOR | c.4870C>T p.Q1624* | Nonsense Mutation (SNP) | VAF 18/106 reads (17%) | catalogued as COSV63869690; called by muse, mutect2, varscan2
- MXRA5 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774812144, COSV54230328; called by muse, mutect2, varscan2
- MYBBP1A | c.3736G>A p.A1246T | Missense Mutation (SNP) | VAF 91/434 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV54595948; called by muse, mutect2, varscan2
- MYCBP2 | c.7316C>T p.A2439V (on ENST00000357337; = p.A2477V on NM_015057.5) | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1409620221, COSV100629228; called by muse, mutect2
- MYCBP2 | c.3635C>A p.S1212* (on ENST00000357337; = p.S1250* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 37/169 reads (22%) | catalogued as COSV100631132, COSV62014151; called by muse, mutect2, varscan2
- MYCBP2 | c.2516-2A>G p.X839_splice (on ENST00000357337; = p.X877_splice on NM_015057.5) | Splice Site (SNP) | VAF 48/211 reads (23%) | catalogued as rs373873724, COSV62014160; called by muse, mutect2, varscan2
- MYH10 | c.403T>G p.S135A | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV52597854; called by muse, varscan2
- MYH9 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs576081279, COSV53384045; called by muse, mutect2, varscan2
- MYMK | c.215A>G p.Y72C | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60600332; called by muse, mutect2, varscan2
- NADSYN1 | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV59811250; called by muse, mutect2, varscan2
- NANOS3 | c.304C>T p.R102C (on ENST00000397555; = p.R121C on NM_001098622.2) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1349261386, COSV59248678; called by muse, mutect2, varscan2
- NASP | c.478del p.T160Qfs*29 | Frame Shift Del (DEL) | VAF 16/105 reads (15%) | catalogued as COSV100601638; called by mutect2, varscan2
- NCAPD3 | c.3125A>G p.H1042R | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV73244846; called by muse, mutect2, varscan2
- NCK1 | c.806T>C p.I269T | Missense Mutation (SNP) | VAF 61/370 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV56636652; called by muse, mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 53/219 reads (24%) | catalogued as rs747914168; called by mutect2, varscan2
- NEFM | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1490631175, COSV55330230, COSV55331398; called by muse, mutect2, varscan2
- NEGR1 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100164481, COSV60831631; called by muse, mutect2, varscan2
- NEURL4 | c.3238G>A p.G1080S | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs745944848, COSV59748304; called by muse, mutect2, varscan2
- NF1 | c.7747_7748del p.R2583Dfs*12 (on ENST00000358273 / NM_001042492.3; = p.R2562Dfs*12 on NM_000267.3) | Frame Shift Del (DEL) | VAF 50/385 reads (13%) | catalogued as rs1135402907; called by pindel, varscan2
- NFATC3 | c.1402-1G>A p.X468_splice | Splice Site (SNP) | VAF 8/75 reads (11%) | catalogued as COSV60472379; called by muse, varscan2
- NGEF | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs749889360, COSV50917253; called by muse, mutect2, varscan2
- NHLRC1 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61481290; called by muse, mutect2, varscan2
- NHP2 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 89/481 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as COSV51070899; called by muse, mutect2, varscan2
- NIBAN1 | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs143246041; called by muse, mutect2, varscan2
- NIPBL | c.247C>A p.L83I | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV56947705; called by muse, mutect2
- NLRC5 | c.3802C>T p.P1268S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV52652338; called by muse, mutect2
- NLRP1 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); catalogued as rs375872650; called by muse, mutect2, varscan2
- NLRP9 | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs758258759, COSV60459756; called by muse, mutect2, varscan2
- NME8 | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52248533; called by muse, mutect2, varscan2
- NOB1 | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV52061205; called by muse, varscan2
- NOBOX | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs200917107; called by mutect2, varscan2
- NOBOX | c.487del p.R163Afs*11 | Frame Shift Del (DEL) | VAF 13/68 reads (19%) | catalogued as rs754069719; called by mutect2, pindel, varscan2
- NOD2 | c.1462T>C p.F488L | Missense Mutation (SNP) | VAF 61/277 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.117); catalogued as COSV56049365; called by muse, mutect2, varscan2
- NPAS3 | c.1676G>A p.R559H (on ENST00000356141 / NM_001164749.2; = p.R527H on NM_022123.3) | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV60827860; called by muse, mutect2, varscan2
- NR2F1 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.508); catalogued as COSV59067800; called by muse, mutect2, varscan2
- NR4A1 | c.603C>A p.S201R | Missense Mutation (SNP) | VAF 138/385 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.125); catalogued as COSV54481250; called by muse, mutect2, varscan2
- NRIP3 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 43/330 reads (13%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.51); catalogued as rs751338383, COSV58469382; called by muse, mutect2, varscan2
- NTRK1 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62324627, COSV62325054; called by muse, mutect2
- NUP210L | c.2072del p.L691Wfs*3 | Frame Shift Del (DEL) | VAF 29/105 reads (28%) | catalogued as rs760869296; called by mutect2, varscan2
- OLFM1 | c.782G>A p.R261Q (on ENST00000371793 / NM_001282611.2; = p.R243Q on NM_014279.5) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.435); catalogued as rs749666045, COSV53277343; called by muse, mutect2
- OR10Z1 | c.265del p.D89Tfs*48 | Frame Shift Del (DEL) | VAF 61/526 reads (12%) | catalogued as rs752054889; called by mutect2, pindel, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 17/122 reads (14%) | catalogued as rs755413956; called by mutect2, varscan2
- OR56A3 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as rs770492176, COSV61568756; called by muse, mutect2, varscan2
- OR5W2 | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV60615321; called by muse, mutect2, varscan2
- OR6K3 | c.542C>A p.T181K (on ENST00000368146; = p.T165K on NM_001005327.2) | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.461); catalogued as COSV63745499; called by muse, mutect2, varscan2
- OR8G1 | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58380586; called by muse, mutect2, varscan2
- OSBPL1A | c.2378del p.N793Mfs*15 (on ENST00000319481 / NM_080597.4; = p.N280Mfs*15 on NM_018030.4) | Frame Shift Del (DEL) | VAF 42/200 reads (21%) | catalogued as rs751106039; called by mutect2, varscan2
- OSM | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.142); catalogued as rs551223066, COSV53161049; called by muse, mutect2
- OTOA | c.1263del p.E422Rfs*58 (on ENST00000286149; = p.E408Rfs*58 on NM_144672.4) | Frame Shift Del (DEL) | VAF 15/76 reads (20%) | catalogued as COSV53750507; called by mutect2, pindel, varscan2
- OTOF | c.4644G>T p.E1548D (on ENST00000272371 / NM_194248.3; = p.E781D on NM_004802.4) | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV55499766; called by muse, mutect2, varscan2
- OTX2 | c.107G>A p.R36Q (on ENST00000408990 / NM_172337.3; = p.R44Q on NM_021728.4) | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59765721; called by muse, mutect2, varscan2
- PACSIN2 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.361); catalogued as rs369451109; called by muse, mutect2, varscan2
- PAGE3 | c.273G>T p.K91N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV100892001, COSV66587148; called by muse, mutect2, varscan2
- PALD1 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs766925536, COSV54971183; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.677A>G p.D226G (on ENST00000374531 / NM_001037293.2; = p.D258G on NM_053016.6) | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.702); catalogued as COSV57117268; called by muse, mutect2, varscan2
- PAM | c.1727dup p.N576Kfs*13 | Frame Shift Ins (INS) | VAF 8/72 reads (11%) | catalogued as rs760406279; called by mutect2, pindel
- PAMR1 | c.1505C>T p.A502V (on ENST00000619888 / NM_001001991.3; = p.A519V on NM_015430.4) | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs984913116, COSV53511053; called by muse, mutect2, varscan2
- PAPLN | c.730C>T p.R244W (on ENST00000554301; = p.R217W on NM_173462.4) | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs763873503, COSV99389307, COSV99389893; called by mutect2, varscan2
- PAPOLA | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs764473731, COSV53480186; called by muse, mutect2, varscan2
- PAPOLB | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68200073; called by muse, mutect2, varscan2
- PAPPA | c.4163G>A p.R1388Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.454); catalogued as rs764379532, COSV60280381; called by muse, mutect2, varscan2
- PAPPA2 | c.3422A>G p.K1141R | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62794179; called by muse, mutect2, varscan2
- PAPSS1 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV54488364; called by muse, mutect2, varscan2
- PAQR4 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs367647268; called by muse, mutect2, varscan2
- PARD3 | c.3113C>T p.T1038M | Missense Mutation (SNP) | VAF 61/369 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs374258573; called by muse, mutect2, varscan2
- PARP11 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs761950257, COSV57394305; called by mutect2, varscan2
- PBX3 | c.1148A>G p.N383S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1428320651, COSV60731499; called by muse, mutect2, varscan2
- PCDH10 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 51/246 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as rs199719551, COSV52090301; called by muse, mutect2, varscan2
- PCDHGA4 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.022); catalogued as rs1277093940, COSV53922218; called by muse, mutect2, varscan2
- PCLO | c.15419A>G p.Q5140R | Missense Mutation (SNP) | VAF 39/513 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV61625444; called by muse, mutect2
- PCSK5 | c.131C>A p.A44D | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV65086667; called by muse, mutect2, varscan2
- PCSK7 | c.2026G>A p.V676I | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs559962536, COSV54063134; called by muse, mutect2, varscan2
- PDCD11 | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 21/125 reads (17%) | catalogued as rs764799582, COSV63933440; called by muse, mutect2, varscan2
- PDE1A | c.707T>G p.L236R | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.145); catalogued as COSV59519310; called by muse, mutect2, varscan2
- PDGFC | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150603208, COSV56847177; called by muse, mutect2, varscan2
- PDZRN3 | c.2792G>A p.R931H | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770783542, COSV55195276, COSV55204605; called by muse, mutect2, varscan2
- PELI2 | c.593del p.G198Afs*73 | Frame Shift Del (DEL) | VAF 54/318 reads (17%) | catalogued as COSV50713636; called by mutect2, pindel, varscan2
- PEX16 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1279952356, COSV53801419; called by muse, mutect2
- PFKP | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746835075, COSV66896474, COSV66897034; called by mutect2, varscan2
- PGLS | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as rs143569199; called by muse, mutect2
- PGLYRP1 | c.280G>C p.G94R | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV50516633; called by muse, mutect2
- PHACTR1 | c.759del p.P254Qfs*59 | Frame Shift Del (DEL) | VAF 14/143 reads (10%) | catalogued as rs749326031; called by mutect2, pindel
- PIBF1 | c.484A>G p.T162A | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV58321793; called by muse, mutect2
- PIGB | c.529dup p.C177Lfs*79 | Frame Shift Ins (INS) | VAF 42/215 reads (20%) | catalogued as rs1356026422; called by mutect2, varscan2
- PIGN | c.128C>A p.A43E | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV104414650, COSV62948506; called by muse, mutect2, varscan2
- PIGR | c.2051C>T p.S684L | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV62903583; called by muse, mutect2, varscan2
- PIGV | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 26/151 reads (17%) | catalogued as rs1369324588, COSV50290962; called by muse, mutect2, varscan2
- PIGZ | c.1467dup p.T490Dfs*2 | Frame Shift Ins (INS) | VAF 32/139 reads (23%) | catalogued as rs759867499; called by mutect2, varscan2
- PIK3CD | c.1982C>T p.A661V | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV63127855; called by muse, mutect2, varscan2
- PJA1 | c.817del p.I273Ffs*61 | Frame Shift Del (DEL) | VAF 38/248 reads (15%) | catalogued as COSV100824736, COSV64052499; called by mutect2, pindel, varscan2
- PKD1L1 | c.5599G>A p.D1867N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as rs753320684, COSV56961589; called by muse, mutect2
- PKN2 | c.232del p.S78Vfs*5 | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | catalogued as rs1335792632, COSV60133695; called by mutect2, pindel, varscan2
- PLCB1 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1171674168, COSV62044138; called by muse, mutect2, varscan2
- PLD2 | c.1792G>A p.G598R | Missense Mutation (SNP) | VAF 74/386 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.075); catalogued as rs368012043; called by muse, mutect2, varscan2
- PLD3 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs754433990, COSV62924399; called by muse, mutect2, varscan2
- PLEC | c.8387A>G p.Q2796R (on ENST00000322810 / NM_201380.4; = p.Q2686R on NM_000445.5) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs781927659, COSV59619452; called by muse, mutect2, varscan2
- PLEKHG1 | c.2026C>T p.R676W | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371565523; called by muse, mutect2, varscan2
- PLEKHG2 | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV52680686; called by muse, mutect2, varscan2
- PLEKHO1 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as rs1256664772, COSV50309961; called by muse, mutect2, varscan2
- PLK3 | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.264); catalogued as COSV59499481; called by muse, mutect2, varscan2
- PLP1 | c.4+2T>C p.X2_splice | Splice Site (SNP) | VAF 8/63 reads (13%) | catalogued as rs113104205, COSV58276082; called by muse, mutect2, varscan2
- PLPPR5 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as COSV54171213; called by muse, mutect2, varscan2
- PLVAP | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141514915; called by muse, mutect2, varscan2
- PLXNA3 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as rs781931954, COSV63753619; called by muse, mutect2, varscan2
- PMEPA1 | c.624del p.S209Afs*61 | Frame Shift Del (DEL) | VAF 16/71 reads (23%) | catalogued as rs751873496; called by mutect2, pindel, varscan2
- PNISR | c.1491del p.E498Sfs*85 | Frame Shift Del (DEL) | VAF 18/114 reads (16%) | catalogued as rs1401239378; called by mutect2, pindel, varscan2
- POLE2 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 60/412 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs1215104033, COSV53559208; called by muse, varscan2
- POLR3A | c.2767A>G p.R923G | Missense Mutation (SNP) | VAF 74/334 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV64930688; called by muse, mutect2, varscan2
- POP1 | c.1195del p.I399Lfs*23 | Frame Shift Del (DEL) | VAF 16/146 reads (11%) | catalogued as COSV62893613; called by mutect2, pindel, varscan2
- POP1 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 38/370 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs781072902, COSV62892312, COSV62893554; called by muse, varscan2
- POP1 | c.1277C>T p.T426M | Missense Mutation (SNP) | VAF 60/392 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748242967, COSV62892316; called by muse, varscan2
- PPARD | c.641A>T p.H214L | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV61099261; called by muse, mutect2, varscan2
- PPARGC1B | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as rs768972512, COSV58528030, COSV58532957; called by muse, mutect2, varscan2
- PPFIA3 | c.2572G>A p.V858M | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV61950684; called by muse, mutect2
- PPP1R10 | c.930del p.V311Yfs*79 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs746108087; called by mutect2, varscan2
- PPP1R10 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as rs375999767; called by muse, mutect2, varscan2
- PPP1R12B | c.335A>T p.E112V | Missense Mutation (SNP) | VAF 49/250 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61115169; called by muse, mutect2, varscan2
- PPP1R13B | c.3268G>A p.A1090T | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs201071102, COSV52450191; called by muse, mutect2, varscan2
- PPP1R13L | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV100714795; called by muse, varscan2
- PPP1R3C | c.642T>A p.D214E | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53287936; called by muse, mutect2, varscan2
- PPP1R42 | c.122A>G p.D41G | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV61207090; called by muse, mutect2
- PPP1R9A | c.2932A>G p.S978G | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as COSV56887510; called by muse, mutect2, varscan2
- PPP6R3 | c.1385C>T p.T462M (on ENST00000393800 / NM_001352375.2; = p.T411M on NM_018312.5) | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761519919, COSV55723691; called by muse, mutect2, varscan2
- PRAMEF10 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.461); catalogued as rs756967247, COSV52434719; called by muse, varscan2
- PRDM16 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752753184, COSV54585853; called by muse, mutect2, varscan2
- PRDM5 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 81/452 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1346294925, COSV53358261; called by muse, mutect2, varscan2
- PREPL | c.1965T>A p.S655R | Missense Mutation (SNP) | VAF 32/376 reads (9%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV53215919; called by muse, mutect2
- PRICKLE4 | c.107C>T p.P36L (on ENST00000359201; = p.P76L on NM_013397.6) | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752836843, COSV100138923, COSV59254307; called by muse, mutect2, varscan2
- PRKCB | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs781780434, COSV100333236, COSV57773104; called by muse, varscan2
- PRMT8 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV54213012; called by muse, mutect2, varscan2
- PROKR1 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 61/363 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58137100; called by muse, mutect2, varscan2
- PRPS1 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 96/573 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV65054244; called by muse, mutect2, varscan2
- PRRT1 | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52997791; called by muse, mutect2, varscan2
- PRUNE2 | c.4281A>C p.K1427N | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV65039865; called by muse, mutect2, varscan2
- PSD2 | c.22T>C p.S8P | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs549790303, COSV51198155; called by muse, varscan2
- PSG2 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 88/416 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1185717951, COSV68884258; called by muse, mutect2, varscan2
- PSMC5 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.861); catalogued as rs1228867189, COSV56738515; called by muse, mutect2, varscan2
- PTPRD | c.1805C>T p.A602V | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV61936876, COSV61956639; called by muse, mutect2, varscan2
- PTPRF | c.4660C>T p.R1554C | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756962072, COSV100740801, COSV63443977; called by muse, mutect2
- PTPRG | c.1619C>T p.T540M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); catalogued as rs779012226, COSV55634982; called by muse, mutect2, varscan2
- PTPRM | c.4184G>A p.R1395H | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs576708975, COSV59852351; called by muse, mutect2, varscan2
- PTPRN2 | c.1066G>T p.A356S | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.098); catalogued as COSV67030880; called by muse, mutect2, varscan2
- PTPRO | c.175A>G p.K59E | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as COSV55506430; called by muse, mutect2, varscan2
- PTPRU | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.049); catalogued as COSV60525000; called by muse, mutect2
- PXDNL | c.2587G>A p.A863T | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV62484164; called by muse, mutect2, varscan2
- R3HDM2 | c.1487A>G p.H496R | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as COSV61286827; called by muse, mutect2, varscan2
- RAB40AL | c.350dup p.G118Wfs*4 | Frame Shift Ins (INS) | VAF 22/124 reads (18%) | catalogued as rs779145147; called by mutect2, varscan2
- RAD51AP2 | c.2595dup p.P866Sfs*4 | Frame Shift Ins (INS) | VAF 8/42 reads (19%) | catalogued as rs767724258; called by mutect2, varscan2
- RADIL | c.2524G>A p.G842R | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1241645383, COSV68200070; called by muse, mutect2
- RASA2 | c.1531C>T p.R511C | Missense Mutation (SNP) | VAF 52/293 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866223197, CM149837, COSV53937796; called by muse, mutect2, varscan2
- RBBP6 | c.2138G>A p.R713H | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.996); catalogued as rs1191974934, COSV60504149; called by muse, mutect2, varscan2
- RBBP6 | c.4712A>C p.K1571T | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as COSV60504158; called by muse, mutect2, varscan2
- RBM15B | c.2296G>A p.A766T | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.656); catalogued as rs781899822, COSV60041857; called by muse, mutect2, varscan2
- RBM43 | c.213del p.V72Lfs*13 | Frame Shift Del (DEL) | VAF 52/264 reads (20%) | catalogued as rs746242773; called by mutect2, varscan2
- RBMX | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 60/386 reads (16%) | catalogued as COSV57808102; called by muse, varscan2
- RBP1 | c.91C>T p.R31C (on ENST00000619087 / NM_001365940.2; = p.R93C on NM_002899.5) | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51676109; called by muse, mutect2, varscan2
- RCAN1 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as rs771689837, COSV58249538; called by muse, mutect2, varscan2
- RCN3 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54541242; called by muse, mutect2, varscan2
- RECQL4 | c.2855del p.G952Afs*92 | Frame Shift Del (DEL) | VAF 23/121 reads (19%) | catalogued as rs1384360858, COSV56740977; called by mutect2, pindel, varscan2
- RELB | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); catalogued as rs770578374, COSV55509337; called by muse, mutect2, varscan2
- RELN | c.7939G>A p.G2647S | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.765); catalogued as rs781392761, COSV58994144; called by muse, mutect2, varscan2
- RELN | c.7406C>T p.T2469I | Missense Mutation (SNP) | VAF 57/317 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV58994155; called by muse, mutect2, varscan2
- RFX3 | c.1900_1901del p.M634Vfs*25 (on ENST00000382004 / NM_134428.3; = p.M634Vfs*27 on NM_002919.4) | Frame Shift Del (DEL) | VAF 18/156 reads (12%) | catalogued as rs1372916670; called by pindel, varscan2
- RGMB | c.356G>T p.R119M (on ENST00000513185 / NM_001366508.1; = p.R160M on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57565041; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 34/132 reads (26%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RIMBP2 | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.11); catalogued as rs138034003; called by muse, mutect2, varscan2
- RING1 | c.517del p.E173Kfs*14 | Frame Shift Del (DEL) | VAF 68/427 reads (16%) | catalogued as rs761874510; called by mutect2, pindel, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 19/91 reads (21%) | catalogued as rs757038390; called by mutect2, varscan2
- RNMT | c.1180del p.T394Hfs*19 | Frame Shift Del (DEL) | VAF 32/172 reads (19%) | catalogued as rs1436309196; called by mutect2, pindel, varscan2
- ROBO1 | c.851A>G p.E284G | Missense Mutation (SNP) | VAF 62/316 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV71392854; called by muse, mutect2, varscan2
- RP1 | c.5665C>T p.Q1889* | Nonsense Mutation (SNP) | VAF 28/163 reads (17%) | catalogued as COSV55113706; called by muse, mutect2, varscan2
- RPH3AL | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs144718442; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL3 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.082); catalogued as rs756974808, COSV53365022; called by muse, mutect2, varscan2
- RPS6KC1 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs766825388, COSV65298233; called by muse, mutect2, varscan2
- RTL5 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV65452846; called by muse, mutect2, varscan2
- RTL9 | c.3618G>T p.E1206D | Missense Mutation (SNP) | VAF 52/261 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV71825475; called by muse, mutect2, varscan2
- RTN2 | c.1516G>A p.V506M | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV55593319; called by muse, mutect2, varscan2
- RUFY2 | c.457del p.M153Wfs*8 | Frame Shift Del (DEL) | VAF 20/102 reads (20%) | catalogued as rs759904440; called by mutect2, varscan2
- RXRA | c.331dup p.L111Pfs*70 | Frame Shift Ins (INS) | VAF 12/66 reads (18%) | catalogued as rs755912201; called by mutect2, varscan2
- RYR1 | c.5453C>T p.A1818V | Missense Mutation (SNP) | VAF 37/240 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs1274823763, COSV62092082, COSV62113411; called by muse, mutect2, varscan2
- RYR1 | c.10184G>A p.R3395Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.389); catalogued as rs543161252, COSV62093565; called by muse, mutect2, varscan2
- RYR2 | c.1877G>A p.R626H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV63675732; called by muse, mutect2
- RYR2 | c.14217del p.F4739Lfs*15 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | catalogued as rs749201569; called by mutect2, varscan2
- SAFB | c.1876C>T p.R626C | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs140739982; called by muse, mutect2, varscan2
- SALL3 | c.2848G>A p.A950T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV73305908; called by muse, mutect2
- SAMD9 | c.3119G>A p.R1040H | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as rs372955426, COSV66077310; called by muse, mutect2, varscan2
- SBF1 | c.5560G>A p.V1854M | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as rs763649071, COSV53291680; called by muse, mutect2, varscan2
- SCAP | c.2560del p.L854* | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as COSV55546266; called by mutect2, pindel, varscan2
- SCARF2 | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs746555186, COSV99839352; called by muse, mutect2, varscan2
- SCN1A | c.5510C>T p.P1837L (on ENST00000303395 / NM_001202435.3; = p.P1826L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/252 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs149225252, COSV57669951; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN3A | c.3950G>A p.R1317Q | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs752111359, COSV51806154, COSV99326969; called by muse, varscan2
- SCYL1 | c.1277T>C p.V426A | Missense Mutation (SNP) | VAF 43/237 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.044); catalogued as COSV54211488; called by muse, mutect2, varscan2
- SEC23A | c.1779del p.F593Lfs*20 | Frame Shift Del (DEL) | VAF 19/98 reads (19%) | catalogued as COSV56979176; called by mutect2, pindel, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 32/120 reads (27%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEL1L2 | c.1372G>T p.G458* | Nonsense Mutation (SNP) | VAF 44/303 reads (15%) | catalogued as COSV53150174; called by muse, mutect2, varscan2
- SEL1L3 | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs951782769, COSV53538451; called by muse, mutect2, varscan2
- SELENOO | c.953C>T p.T318M | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755927400, COSV66598822; called by muse, mutect2, varscan2
- SELENOO | c.1351+2T>C p.X451_splice | Splice Site (SNP) | VAF 51/307 reads (17%) | catalogued as COSV66598825; called by muse, mutect2, varscan2
- SEMA3D | c.1806del p.F602Lfs*36 | Frame Shift Del (DEL) | VAF 40/274 reads (15%) | catalogued as CM135803; called by mutect2, varscan2
- SETD1A | c.2121dup p.G708Rfs*117 | Frame Shift Ins (INS) | VAF 24/143 reads (17%) | catalogued as rs754369980; called by mutect2, varscan2
- SETD2 | c.3881G>A p.G1294D | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.05); catalogued as COSV57434368; called by muse, mutect2, varscan2
- SETDB2 | c.1516del p.M506Wfs*24 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | catalogued as rs768645211; called by mutect2, varscan2
- SF3B2 | c.2625del p.K875Nfs*59 | Frame Shift Del (DEL) | VAF 30/178 reads (17%) | catalogued as rs759211171; called by mutect2, varscan2
- SGK3 | c.1320+2T>C p.X440_splice | Splice Site (SNP) | VAF 6/23 reads (26%) | catalogued as COSV61894159; called by muse, mutect2, varscan2
- SGO1 | c.973del p.M325Cfs*28 | Frame Shift Del (DEL) | VAF 15/79 reads (19%) | catalogued as rs747473028; called by mutect2, varscan2
- SH3RF1 | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52919633; called by muse, mutect2, varscan2
- SHISA2 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs113091428; called by muse, mutect2, varscan2
- SIDT2 | c.2248C>T p.L750F | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0.029); catalogued as rs1471933232, COSV54056149; called by muse, varscan2
- SIPA1L3 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs772021253, COSV55911523; called by muse, mutect2, varscan2
- SKIV2L | c.1838G>A p.G613D | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.54); catalogued as COSV64810950; called by muse, mutect2, varscan2
- SKIV2L | c.2446del p.E816Rfs*3 | Frame Shift Del (DEL) | VAF 34/216 reads (16%) | catalogued as rs768446878; called by mutect2, pindel, varscan2
- SLC17A8 | c.150A>T p.E50D | Missense Mutation (SNP) | VAF 140/400 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.254); catalogued as COSV60122974; called by muse, mutect2, varscan2
- SLC22A23 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.217); catalogued as rs766490228, COSV66677038; called by muse, mutect2, varscan2
- SLC22A7 | c.1214C>T p.T405M (on ENST00000372585 / NM_153320.2; = p.T403M on NM_006672.3) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs1323605027, COSV51483465; called by muse, mutect2, varscan2
- SLC29A4 | c.107C>A p.A36E | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.086); catalogued as COSV51873504; called by muse, mutect2, varscan2
- SLC2A7 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0.01); catalogued as rs774929471, COSV68901706; called by muse, mutect2, varscan2
- SLC52A1 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs137937212; called by muse, mutect2, varscan2
- SLC5A9 | c.1490T>C p.L497P | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52582725; called by muse, mutect2, varscan2
- SLC7A11 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs186693425, COSV54928631, COSV54929311; called by muse, mutect2, varscan2
- SLC9C2 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs1250211864, COSV62943501; called by muse, mutect2, varscan2
- SLCO3A1 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs745409648, COSV59227599, COSV59240256; called by muse, mutect2, varscan2
- SLITRK1 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV65674927; called by muse, mutect2, varscan2
- SMAD7 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759611060, COSV50988773; called by muse, mutect2, varscan2
- SMARCAD1 | c.1040del p.N347Mfs*24 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | catalogued as rs754697669; called by mutect2, varscan2
- SMC1A | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as CM071096, COSV59128560; called by muse, mutect2, varscan2
- SMC6 | c.1228del p.I410Yfs*4 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | catalogued as rs760667210; called by mutect2, varscan2
- SNAPC4 | c.2240C>T p.A747V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53732030; called by muse, mutect2, varscan2
- SNED1 | c.3395T>C p.L1132S | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV60021581; called by muse, mutect2, varscan2
- SNX4 | c.312G>A p.W104* | Nonsense Mutation (SNP) | VAF 43/160 reads (27%) | catalogued as COSV52537450; called by muse, mutect2, varscan2
- SOX7 | c.463del p.A155Rfs*116 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | catalogued as rs769092194; called by mutect2, pindel, varscan2
- SP3 | c.2236T>C p.S746P | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.731); catalogued as rs777854788, COSV59466912; called by muse, mutect2, varscan2
- SPATS2 | c.851G>T p.R284L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58917757; called by mutect2, varscan2
- SPATS2 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 56/309 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV58917764; called by muse, mutect2, varscan2
- SPEG | c.3766G>A p.G1256S | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1173927707, COSV56665085; called by muse, mutect2, varscan2
- SPOCD1 | c.611G>T p.R204M | Missense Mutation (SNP) | VAF 63/361 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.431); catalogued as COSV57095212; called by muse, mutect2, varscan2
- SPTAN1 | c.2294G>A p.R765H | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1163379622, COSV63986157; called by muse, mutect2, varscan2
- SPTBN1 | c.5263G>A p.V1755M | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs779986830, COSV61687080; called by muse, mutect2, varscan2
- SPTBN2 | c.3929G>A p.R1310H | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.549); catalogued as rs201852582, COSV59449715; ClinVar: not provided; called by muse, mutect2, varscan2
- SPTLC3 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs375500511, COSV65463690; called by muse, mutect2, varscan2
- SRRM2 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 26/136 reads (19%) | catalogued as COSV57070879; called by muse, mutect2, varscan2
- SSR4 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as rs142189119, COSV51245956; called by muse, mutect2, varscan2
- ST18 | c.1862del p.N621Ifs*10 | Frame Shift Del (DEL) | VAF 30/242 reads (12%) | catalogued as rs1563701552; called by mutect2, varscan2
- ST6GAL2 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 19/94 reads (20%) | PolyPhen probably damaging (0.998); catalogued as rs762559384, COSV62416291; called by muse, mutect2, varscan2
- ST8SIA3 | c.988A>G p.T330A | Missense Mutation (SNP) | VAF 11/126 reads (9%) | PolyPhen benign (0.207); catalogued as COSV60653728; called by muse, mutect2
- ST8SIA4 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 11/74 reads (15%) | PolyPhen benign (0.003); catalogued as COSV51508445; called by muse, mutect2, varscan2
- STC2 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 62/285 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.085); catalogued as rs1277653641, COSV54178110, COSV54182193; called by muse, mutect2, varscan2
- STK11IP | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs766660134, COSV55247067, COSV99822814; called by muse, mutect2, varscan2
- STK17B | c.581A>G p.E194G | Missense Mutation (SNP) | VAF 57/264 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55827713; called by muse, mutect2, varscan2
- STRA6 | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs140894233; called by muse, mutect2, varscan2
- STRAP | c.444del p.A149Lfs*26 | Frame Shift Del (DEL) | VAF 56/262 reads (21%) | catalogued as rs1470408003; called by mutect2, pindel, varscan2
- STX17 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs779595097, COSV52283062; called by muse, mutect2, varscan2
- SULF1 | c.223del p.A75Pfs*8 | Frame Shift Del (DEL) | VAF 14/107 reads (13%) | catalogued as rs747316268, COSV52690552; called by mutect2, pindel, varscan2
- SULF1 | c.2611G>T p.G871C | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV52677960, COSV99482748; called by muse, mutect2, varscan2
- SYCP1 | c.660A>C p.K220N | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV65696209; called by muse, mutect2, varscan2
- SYCP1 | c.1884del p.G629Vfs*8 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | catalogued as rs762984894, COSV65697419; called by mutect2, varscan2
- SYCP2 | c.526del p.M176* | Frame Shift Del (DEL) | VAF 17/128 reads (13%) | catalogued as rs1346657016; called by mutect2, varscan2
- SYN2 | c.1277C>A p.P426H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70285124; called by mutect2, varscan2
- SYNE2 | c.12227_12229del p.E4076del | In Frame Del (DEL) | VAF 32/148 reads (22%) | catalogued as rs748493867; called by pindel, varscan2
- SYNJ1 | c.1146G>T p.K382N | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.783); catalogued as COSV59143929, COSV59146074; called by muse, mutect2, varscan2
- SYTL2 | c.2101C>T p.R701W (on ENST00000528231 / NM_001162951.2; = p.R677W on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142815066; called by muse, mutect2, varscan2
- SZT2 | c.8174C>T p.P2725L (on ENST00000634258 / NM_001365999.1; = p.P2668L on NM_015284.4) | Missense Mutation (SNP) | VAF 55/345 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as rs1340491489, COSV65168510; called by muse, mutect2, varscan2
- TAF1 | c.5462C>T p.P1821L (on ENST00000373790 / NM_138923.4; = p.P1842L on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as rs763664628, COSV52110313; called by muse, mutect2
- TAF5L | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51078412; called by muse, mutect2, varscan2
- TAMM41 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 60/310 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV56071399, COSV56072390; called by muse, mutect2, varscan2
- TANC2 | c.4520C>T p.P1507L | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs902412126, COSV67332606; called by muse, mutect2, varscan2
- TAS1R1 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.806); catalogued as rs534950007, COSV60227492; called by muse, mutect2, varscan2
- TAS2R42 | c.745del p.S249Pfs*18 | Frame Shift Del (DEL) | VAF 19/140 reads (14%) | catalogued as rs753101364; called by mutect2, varscan2
- TBC1D12 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs373749349; called by muse, mutect2, varscan2
- TBC1D2B | c.2521G>A p.V841I | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.951); catalogued as rs750959599, COSV56039912; called by muse, mutect2, varscan2
- TBKBP1 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as rs184407093, COSV64653447; called by muse, mutect2, varscan2
- TBL3 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147036287; called by muse, mutect2, varscan2
- TBX5 | c.860T>C p.L287S | Missense Mutation (SNP) | VAF 80/200 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.163); catalogued as COSV59859872; called by muse, mutect2, varscan2
- TCF20 | c.3064C>T p.R1022W | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1426050114, COSV59489707; called by muse, mutect2, varscan2
- TENM1 | c.6512G>A p.R2171H | Missense Mutation (SNP) | VAF 44/261 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs762426434, COSV64428703; called by muse, mutect2, varscan2
- TENM1 | c.4351C>T p.R1451C | Missense Mutation (SNP) | VAF 59/326 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs746639113, COSV64428709; called by muse, mutect2, varscan2
- TENM3 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated, low confidence (0.65); PolyPhen possibly damaging (0.665); catalogued as COSV69303533; called by muse, mutect2, varscan2
- TENM4 | c.6235G>A p.A2079T | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772029249, COSV53605877; called by muse, mutect2, varscan2
- TENT4A | c.2299C>T p.H767Y | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.792); catalogued as COSV50094885; called by muse, mutect2, varscan2
- TEP1 | c.4408G>A p.V1470I | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs61739723, COSV52990494; called by muse, mutect2, varscan2
- TET1 | c.65del p.K22Rfs*23 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | catalogued as rs1196853334; called by mutect2, varscan2
- TEX15 | c.5540C>T p.S1847L (on ENST00000256246; = p.S2230L on NM_001350162.2) | Missense Mutation (SNP) | VAF 46/331 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as rs778747787, COSV56344148; called by muse, mutect2, varscan2
- TEX15 | c.3018del p.A1007Lfs*12 (on ENST00000256246; = p.A1390Lfs*12 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 84/462 reads (18%) | catalogued as rs753315680; called by mutect2, varscan2
- THNSL2 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs755201587, COSV59082444; called by muse, mutect2, varscan2
- THRAP3 | c.304G>T p.G102* | Nonsense Mutation (SNP) | VAF 64/316 reads (20%) | catalogued as COSV63567248; called by muse, mutect2, varscan2
- THRAP3 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV100663155, COSV63567254; called by muse, mutect2, varscan2
- TIRAP | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV67024026; called by muse, mutect2, varscan2
- TJP2 | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55264716; called by muse, mutect2, varscan2
- TLL1 | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV50269633; called by muse, mutect2, varscan2
- TLL1 | c.2665G>A p.G889R | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376169735; called by muse, mutect2, varscan2
- TLR2 | c.1360T>C p.C454R | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766467979, COSV52605595; called by muse, mutect2, varscan2
- TMCC3 | c.281C>A p.A94E | Missense Mutation (SNP) | VAF 123/353 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54152619, COSV54153235; called by muse, mutect2, varscan2
- TMEM131L | c.4189G>A p.V1397I | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV53642636; called by muse, mutect2, varscan2
- TMEM132A | c.1957C>T p.R653W (on ENST00000453848 / NM_178031.3; = p.R654W on NM_017870.4) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.947); catalogued as rs779426844, COSV50003274; called by muse, mutect2, varscan2
- TMEM184A | c.133del p.A45Pfs*92 | Frame Shift Del (DEL) | VAF 19/100 reads (19%) | catalogued as COSV52473497; called by mutect2, pindel, varscan2
- TMEM266 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 55/322 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as rs776711597, COSV66379000; called by muse, mutect2, varscan2
- TMUB2 | c.603C>T p.S201= (on ENST00000538716 / NM_001353177.2; = p.S181= on NM_024107.3 and 5 other RefSeq transcripts) | Splice Region (SNP) | VAF 21/88 reads (24%) | catalogued as rs369574186, COSV60228511; called by muse, mutect2, varscan2
- TNC | c.667A>C p.S223R | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as COSV60783074; called by muse, mutect2, varscan2
- TNIP3 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.36); catalogued as rs746782978, COSV50246703; called by muse, mutect2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TNPO2 | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 53/261 reads (20%) | catalogued as COSV63507880, COSV63508911; called by muse, mutect2, varscan2
- TNS2 | c.3977C>T p.T1326M (on ENST00000314250 / NM_170754.4; = p.T1336M on NM_015319.2) | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as rs758034845, COSV56852888; called by muse, mutect2, varscan2
- TOP3B | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769874024, COSV64116280; called by muse, mutect2, varscan2
- TOPBP1 | c.4403A>G p.Y1468C | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53434396; called by muse, mutect2, varscan2
- TPP2 | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1231094275, COSV65751758; called by muse, mutect2, varscan2
- TPR | c.5828T>C p.V1943A | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV66600451; called by muse, mutect2, varscan2
- TRAPPC11 | c.2109G>A p.W703* | Nonsense Mutation (SNP) | VAF 25/210 reads (12%) | catalogued as COSV58215599; called by muse, mutect2, varscan2
- TRIM39 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV64955119; called by muse, mutect2, varscan2
- TRIM50 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.703); catalogued as rs368619027, COSV52719550; called by muse, mutect2, varscan2
- TRIM54 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV56082691; called by muse, mutect2, varscan2
- TRMT112 | c.46del p.V16Wfs*30 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | catalogued as rs762738556, COSV50008423; called by mutect2, varscan2
- TRMT2A | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs200994055; called by muse, mutect2, varscan2
- TRPC1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.939); catalogued as rs1334283044; called by muse, mutect2
- TRPM1 | c.2430del p.K810Nfs*60 | Frame Shift Del (DEL) | VAF 25/135 reads (19%) | catalogued as rs761882630; called by mutect2, pindel, varscan2
- TRPM2 | c.529del p.A177Pfs*6 | Frame Shift Del (DEL) | VAF 19/136 reads (14%) | catalogued as rs762935066, COSV55967995; called by mutect2, pindel, varscan2
- TRPM6 | c.3049C>T p.P1017S | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773157692, COSV62506308; called by muse, varscan2
- TRPM6 | c.1989A>C p.E663D | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.224); catalogued as COSV62506323; called by muse, mutect2, varscan2
- TSNARE1 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs992297204, COSV56173471; called by muse, mutect2, varscan2
- TSPAN7 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs868156656, COSV54529429; called by muse, mutect2, varscan2
- TSPOAP1 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs370827321; called by muse, mutect2
- TSPYL5 | c.409dup p.R137Pfs*18 | Frame Shift Ins (INS) | VAF 22/171 reads (13%) | catalogued as rs775143186; called by mutect2, pindel, varscan2
- TTBK1 | c.1631T>C p.V544A | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52489684; called by muse, mutect2, varscan2
- TTC6 | c.916A>G p.I306V (on ENST00000267368; = p.I1672V on NM_001310135.3) | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV99941980; called by muse, mutect2, varscan2
- TTC7A | c.520C>A p.L174I | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55409853; called by muse, mutect2, varscan2
- TTK | c.2571del p.K857Nfs*36 | Frame Shift Del (DEL) | VAF 13/73 reads (18%) | catalogued as rs768996038, COSV57882295; called by pindel, varscan2
529 further variants in this file (224 protein-altering or splice-affecting, 277 silent, 28 other) are not listed here.
